Somatic mutation profile of tumor specimen TCGA-3A-A9IN-01A (aliquot TCGA-3A-A9IN-01A-11D-A397-08) from TCGA case TCGA-3A-A9IN, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 62.4 years (22,799 days).
Specimen TCGA-3A-A9IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dadb0383-ae69-40a9-8e57-a8f1a739d995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IN-10A (Blood Derived Normal), aliquot TCGA-3A-A9IN-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aafc9e08-3a14-4551-b629-77592934a930

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 6, Silent 4, Nonsense Mutation 2, Splice Region 1, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.68-1G>A p.X23_splice | Splice Site (SNP) | VAF 110/242 reads (45%) | catalogued as rs1131691174, COSV100776697; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1102_1104del p.E368del | In Frame Del (DEL) | VAF 177/423 reads (42%) | catalogued as rs869025185; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARL4C | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.928); catalogued as COSV100327071, COSV60214738; called by muse, mutect2, varscan2
- C10orf71 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 43/84 reads (51%) | catalogued as rs1247470561, COSV100110492; called by muse, mutect2, varscan2
- CSTF3 | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100124251; called by muse, mutect2
- FLNC | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1258983653, COSV57965898; called by muse, mutect2, varscan2
- H3-5 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100461701; called by muse, mutect2, varscan2
- HTRA2 | c.1209C>T p.H403= | Splice Region (SNP) | VAF 10/243 reads (4%) | catalogued as COSV99239848; called by muse, mutect2
- MRPL14 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 402/785 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.416); catalogued as COSV100921049; called by muse, mutect2, varscan2
- MYOM2 | c.4233G>C p.E1411D | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as COSV100038065; called by muse, mutect2, varscan2
- NEO1 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 162/339 reads (48%) | catalogued as COSV56066913; called by muse, mutect2, varscan2
- NIBAN3 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 229/641 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99962612; called by muse, mutect2, varscan2
- NSUN7 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 157/528 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as rs769733094, COSV100349531; called by muse, mutect2, varscan2
- OR3A3 | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 163/538 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99351490; called by muse, mutect2, varscan2
- PNPLA6 | c.1877C>T p.A626V (on ENST00000414982 / NM_001166111.2; = p.A578V on NM_006702.5) | Missense Mutation (SNP) | VAF 54/696 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1360212457, COSV55375615; called by muse, mutect2
- PXDN | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as rs1480667163, COSV99414478; called by muse, mutect2, varscan2
- STOML3 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV101105364; called by muse, mutect2
- TDRD10 | c.500T>C p.M167T | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV100873177; called by muse, mutect2, varscan2
- TSHZ1 | c.1273C>A p.H425N (on ENST00000580243 / NM_001308210.2; = p.H380N on NM_005786.6) | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100433873; called by muse, mutect2, varscan2
- WDR33 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100460501; called by muse, mutect2, varscan2
- ZNF331 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 75/1179 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99467474; called by muse, mutect2
- ZNF681 | c.1607G>T p.C536F | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101267542; called by muse, mutect2, varscan2
- ATG14 | c.160_164del p.T54Rfs*31 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | called by pindel, varscan2*
- ATP5F1A | c.856del p.Q286Sfs*23 | Frame Shift Del (DEL) | VAF 99/363 reads (27%) | called by mutect2, pindel, varscan2
- CTSV | c.340del p.L114Ffs*13 | Frame Shift Del (DEL) | VAF 117/410 reads (29%) | called by mutect2, pindel, varscan2
- DAXX | c.837del p.P280Lfs*14 | Frame Shift Del (DEL) | VAF 160/364 reads (44%) | called by mutect2, pindel, varscan2
- PRIMPOL | c.1656_1665del p.L553Kfs*7 | Frame Shift Del (DEL) | VAF 71/309 reads (23%) | called by mutect2, pindel, varscan2
- SNAI3 | c.728_729del p.S243Kfs*41 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- NTNG1 | c.858C>T p.Y286= | Silent (SNP) | VAF 150/298 reads (50%) | catalogued as COSV53983712, COSV53985417, COSV99638802; called by muse, mutect2, varscan2
- SLC4A7 | c.2250T>C p.Y750= | Silent (SNP) | VAF 61/626 reads (10%) | catalogued as COSV99840151; called by muse, mutect2
- SLC6A8 | c.1281C>T p.T427= | Silent (SNP) | VAF 58/773 reads (8%) | catalogued as rs368950125, COSV99466148; ClinVar: likely benign; called by muse, mutect2
- TNFRSF11A | c.1185C>T p.S395= | Silent (SNP) | VAF 24/328 reads (7%) | catalogued as rs754481352, COSV99500488; called by muse, mutect2
- ST8SIA4 | c.798-4360T>A | Intron (SNP) | VAF 121/326 reads (37%) | catalogued as rs778485454, COSV99185424; called by muse, mutect2, varscan2
